Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A0TN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A0TN-01A (Primary Tumor).

[page 1 of 7]
Name: [REDACTED]
Address: [REDACTED]

Surg.

MR No.: [REDACTED]
Service: GYNECOLOGY
Surgeon: [REDACTED]

Taken

DIAGNOSIS

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, FOCALLY KERATINIZING, 7.0 CM IN GREATEST DIMENSION
- CARCINOMA INVADERS TO A DEPTH OF 7 MM (TOTAL WALL THICKNESS 10 MM)
- FOCAL LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED
- EXTENSIVE CARCINOMA IN-SITU (CIN III) IS PRESENT ADJACENT TO INVASIVE CARCINOMA (SEE COMMENT)

PARAMETRIUM, RIGHT AND LEFT, RADICAL HYSTERECTOMY

- NO CARCINOMA IDENTIFIED
- LARGE VESSELS WITH ATHEROSCLEROSIS AND RECANALIZED THROMBI

VAGINA, CUFF, MARGIN, RADICAL HYSTERECTOMY

- FOCAL PARAKERATOSIS
- NO CARCINOMA OR DYSPLASIA IDENTIFIED

ICD-O-3
carcinoma, squamous cell,
keratinizing, NOS 8071/3
Site: cervix, NOS C53.9

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- GESTATIONAL ENDOMETRIUM

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- IMPLANTATION SITE

See is (circle):		

LYMPH NODES, RIGHT OBTURATOR, EXCISION

- METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF SEVEN LYMPH NODES (2/7)
- FOCAL EXTRACAPSULAR EXTENSION BY CARCINOMA IS IDENTIFIED
- ACUTE INFLAMMATION AND FOCAL ABSCESS FORMATION (SEE COMMENT)
- LYMPHOID HYPERPLASIA

LYMPH NODES, LEFT OBTURATOR, EXCISION

~~NO CARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2)~~

LYMPH NODE, LEFT EXTERNAL EXCISION

- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

FETUS, TERMINATION

- INTACT FEMALE FETUS, 18 TO 19 WEEKS GESTATIONAL AGE BY FETOPSY MEASUREMENTS
- NO CONGENITAL ANOMALIES IDENTIFIED

PLACENTA, TERMINATION

- IMMATURE PLACENTA CONSISTENT WITH GESTATIONAL AGE

[page 2 of 7]
Name:

Surg. Path. No.:

DIAGNOSIS (continued)

UMBILICAL CORD, TERMINATION

- THREE VESSEL UMBILICAL CORD WITH NO HISTOPATHOLOGIC ABNORMALITY

FETAL MEMBRANES, TERMINATION

- FETAL MEMBRANES WITH NO HISTOPATHOLOGIC ABNORMALITY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis), and that I have reviewed and approved this report.

SPECIMEN(S) SUBMITTED

- Part 1: UTERUS AND FETUS
- Part 2: LEFT EXTERNAL NODES
- Part 3: LEFT OBTURATOR NODES
- Part 4: RIGHT OBTURATOR NODES

HISTORY

The patient is a year old woman with an intrauterine pregnancy at 17 weeks estimated gestational age and poorly differentiated ~~invasive squamous cell carcinoma of the cervix. Operative~~ procedure: Examination under anesthesia, exploratory laparotomy, radical hysterectomy, lymph node sampling, and pregnancy termination.

GROSS

The specimens are received in four containers of formalin, each labeled with the patient's name. The first specimen container is labeled "uterus and cervix." It contains a previously opened and fixed uterus with attached placenta weighing 505 grams and

[page 3 of 7]
Name:

Surg. Path. No.:

GROSS (continued)

measuring 18 cm fundus to ectocervix, 8.0 cm cornu to cornu, and 7.0 cm anterior to posterior. The attached vaginal cuff measures 4.0 cm in length and 8.0 cm in width posteriorly and 3.0 cm in length and 5.5 cm in width anteriorly. Only a small portion of ectocervix is visible measuring 1.2 x 1.2 cm. It is yellow with a central area of hemorrhage measuring 0.4 cm. The endocervical canal is light tan and measures 2.5 cm in length. Replacing most of the ectocervix is a polypoid, lobulated, poorly circumscribed mass measuring 7.0 x 5.0 cm. It involves mainly the anterior portion of the ectocervix. It abuts the endocervical canal anteriorly and posteriorly. It is present 4.0 cm from the posterior vaginal cuff margin and 3.0 cm from the anterior vaginal cuff margin. Sections show the tumor to invade to a depth of 2.4 cm out of a wall thickness of 3.1 cm anteriorly. Posteriorly the tumor invades to a depth of 1.9 cm where the wall thickness measures 3.3 cm. Labeled CX1 and EC1 - anterior cervix and endocervix cut in continuity; labeled CX2 - anterior cervix; labeled CX3, EC3A, EC3B - anterior cervix and endocervix cut in continuity; labeled CX4, EC4A, EC4B - anterior cervix and endocervix cut in continuity; labeled CX5 and EC5 - posterior cervix and endocervix in continuity; labeled CX6 and EC6 - posterior cervix and endocervix in continuity; labeled CX7 and EC7 - posterior cervix and endocervix in continuity; labeled CX8 and EC8 - posterior cervix and endocervix in continuity; labeled - shave margin of the anterior vaginal cuff; labeled VCP1 and VCP2 - shave margin of the posterior vaginal cuff. The previously inked right parametrial soft tissue measures 5.0 x 3.5 x 0.8 cm. Sectioning and palpation demonstrates yellow adipose tissue admixed with white fibrous tissue. It is not grossly involved by tumor. Labeled RP1 through RP4 - right parametrial soft tissue. The previously inked left parametrial soft tissue measures 4.5 x 2.5 x 0.7 cm. Sectioning and palpation demonstrate yellow adipose tissue admixed with white fibrous tissue. It is grossly uninvolved by tumor. Labeled LP1 and LP2 - left parametrial soft tissue. The majority of the myometrium is covered by a previously sectioned placenta and decidual tissue. The myometrium is tan, trabeculated, and has a thickness of 2.5 cm. The decidualized tissue covering it is light tan, nodular, and glistening. The placenta measures 16 x 6.0 x 2.0 cm. There is a stub where an umbilical cord attached measuring 2.5 cm from the closest disc edge. The placental parenchyma is light brown and homogeneous. There is no gross evidence of vascular thrombosis or infarction. The uterine serosa is light tan, slightly wrinkled, and glistening. Only a small portion of fetal membrane is identified. It is slightly opaque and firm, perhaps owing to previous fixation. Labeled P1A and P1B - placenta and underlying myometrium submitted in continuity; labeled P2A and P2B - placenta and underlying myometrium submitted in continuity. Labeled FM - fragment of fetal membrane.

[page 4 of 7]
Name:

Surg. Path. No.:

GROSS (continued)

Received in the same container is a fetus with attached umbilical cord weighing 207 grams. The umbilical cord measures 25 cm in length, 0.6 cm in diameter, and has three-vessel morphology. It attaches at the umbilicus in the usual fashion. Labeled - three sections of umbilical cord. The fetus measures 14 cm in head circumference, 13.4 cm in chest circumference, 10.4 cm in abdominal circumference, 14.5 cm crown rump length, 23.0 cm crown heel length, and 3.1 cm in foot length. It appears normocephalic with open fontanelles. The cranial cavity contains a brain weighing 32 gm with normally formed hemispheres and cerebellum. The cranial nerves appear grossly intact. The ears do not appear to be low or high set. The eyes are fused and there is an outer canthal distance of 3.5 and an inner canthal distance of 1.4 cm. The nares are patent and there is no deviated septum. The mouth and mandible are normally formed, the tongue is of normal calibre, and the palate is intact. The oropharynx is clear. The neck is normally formed without evidence of webbing. The arms and legs are normally formed and there are five toes and five fingers on each foot and hand, respectively. There is no evidence of webbing. Breast buds are not visible on the chest. The chest and abdominal wall are intact. The spinal cord shows normal curvature without defects or indentations or herniations. The genitalia are ambiguous for sex. The anus is patent. No body hair is identified on either the scalp or on any other body surface. The head is normocephalic. Overall, there are no dysmorphic features. The skin is light tan and somewhat translucent. Sections of the neck demonstrate a trachea and esophagus that are clear. The thyroid is identified in the normal anatomic location, is light tan, and shows normal morphology. Near the thoracic cavity a thymus is identified that is lobular and unremarkable. The thymus weighs 0.3 grams. Opening the chest cavity demonstrates clear pleural cavities and a right and left lung with three and two lobes, respectively. The right and left lungs are light tan and sections demonstrate homogeneous tan parenchyma without crepitation evident. The right and left lungs weigh 2.9 and 2.5 grams, respectively. They are in the usual anatomic position. The heart is in the usual anatomic position and weighs 1.5 grams. The right and left atria and ventricles are identified in their usual anatomic position. The great vessels pursue a normal course. The foramen ovale is identified and is patent. There are no atrial or septal defects. The aortic, pulmonary, tricuspid, and mitral valves demonstrate normal morphology. The myocardial tissue is light brown. The aorta pursues a normal course in the thoracic and abdominal areas. Labeled A - aorta; labeled B - heart; labeled C - thymus; labeled D - trachea including thyroid; labeled E - right lung; labeled F - left lung. Opening the abdominal cavity demonstrates a clear cavity. The stomach is normally rotated and the appendix is in the usual anatomic position. The

[page 5 of 7]
Name: -

Surg. Path. No.:

GROSS (continued)

liver is in the usual anatomic position, weighs 9.1 grams, and has a normal anatomic morphology. Sections demonstrate homogeneous brown parenchyma. The gallbladder is in the usual anatomic position. Bile is not expressed from the ampulla of Vater upon pressure being placed over the gallbladder; labeled G - liver; labeled H - gallbladder. The right and left adrenals are in the usual anatomic position and weigh 0.4 and 0.6 grams, respectively. Sections demonstrate a poor corticomedullary demarcation. Labeled I1 and I2 - right and left adrenals, respectively. The pancreas is in the usual anatomic position, is tan, lobular, and weighs 0.2 grams. The spleen weighs 0.4 grams, is dark brown, and sections show homogeneous maroon tissue within. Labeled J - pancreas; labeled K - spleen. The right and left kidneys are in the usual anatomic position and their capsules strip easily. The right and left kidneys weigh 1.1 and 1.0 grams, respectively. They are lobular in their configuration. Sections demonstrate a poor corticomedullary demarcation. Their attached ureters pursue a normal course and empty into the bladder. Labeled L1 and L2 - right and left kidneys, respectively. The esophagus and stomach are clear and unremarkable grossly. The small intestine is clear and unremarkable. The large intestine contains a small amount of dark green material but is unremarkable. Labeled M - stomach and esophagus; labeled N1 and N2 - small and large intestine, respectively. The bladder and uterus and ovaries are identified in the normal anatomic position. The bladder is not hypoplastic. The uterus contains a myometrium that is white. An endometrium is not identifiable. Labeled O1 - ovaries; labeled O2 - cross sections demonstrating rectum, uterus, and bladder. Labeled P1 - section of rib cage including ossification center; labeled P2 - section of skin. Labeled Q1 - spinal cord; labeled Q2 - cerebellum; labeled Q3 - section of cortical hemisphere. Jar 4.

The second specimen container is labeled "left external nodes." It contains a single unoriented fragment of dark blue and white fibrous tissue admixed with yellow adipose tissue measuring 4.0 x 1.0 x 0.8 cm. Two putative lymph nodes are identified on sectioning and palpation measuring 0.5 and 1.0 cm in greatest dimension. ~~Each is bisected and a half of each is placed in a cassette labeled R. Jar 1.~~

The third specimen container is labeled "left obturator nodes." It contains a single unoriented fragment of white fibrous tissue admixed with dark brown hemorrhage measuring 4.0 x 2.0 x 1.0 cm. Sectioning and palpation demonstrate three putative lymph nodes ranging in size from 0.5 to 1.5 cm in greatest dimension. Each is bisected and a half of each is placed in a cassette labeled S. Jar 1.

The fourth specimen container is labeled "right obturator nodes."

[page 6 of 7]
Name:

Surg. Path. No.: 1

GROSS (continued)

It contains two unoriented fragments of white fibrous tissue admixed with yellow adipose tissue and hemorrhage, measuring 4.0 x 2.0 x 0.8 and 7.0 x 2.5 x 1.8 cm in dimension, respectively. Multiple lymph nodes are identified upon sectioning and palpation ranging in size from 0.5 to 3.0 cm. All of them are bisected and a half of each is placed in a cassette labeled T1 through T5. Jar 1.

COMMENT

The cervix is nearly completely replaced by a 7.0 cm poorly differentiated squamous cell carcinoma exhibiting focal keratinization. At its most deeply invasive, the tumor invades to a maximum depth of 7 mm where the wall thickness is 10 mm. Extensive carcinoma in situ (CIN III) is present adjacent to invasive tumor. A second and possibly multiple, smaller foci of invasive carcinoma, clearly separate from the main tumor mass, is present beneath areas of CIN III. Lymphatic invasion is identified but is focal. No extension into parametrial tissue is present. The vaginal cuff margin is free of carcinoma. Metastatic squamous cell carcinoma is present in two of seven right obturator lymph nodes. Focal extracapsular extension by carcinoma is identified. One right obturator lymph node contains extensive acute inflammation and focal abscess formation. This finding raises the possibility of cat scratch disease, lymphogranuloma venereum, or another suppurative infections. Two left obturator and one external iliac lymph nodes are free of carcinoma. The lymph nodes exhibit marked lymphoid hyperplasia.

An intact female fetus was present within the endometrial cavity. The estimated gestational age by fetopsy measurements is 18 to 19 weeks. No congenital anomalies were identified on gross examination. Microscopic sections of various tissues revealed no histologic abnormalities. The umbilical cord contains three vessels and is without histopathologic abnormality. The fetal membranes are without histopathologic abnormality. The placenta is immature consistent with the gestational age.

SYNOPTIC REPORTING FORM FOR UTERINE CERVICAL NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Squamous cell (epidermoid) carcinoma, invasive type
Keratinizing subtype
3. The MAXIMUM DEPTH OF TUMOR INVASION is 7 mm.
4. The BREADTH (MAXIMUM HORIZONTAL DIMENSION) OF THE TUMOR is 70 mm.

[page 7 of 7]
Name:

Surg. Path. No.:

COMMENT (continued)

5. The TOTAL THICKNESS OF THE CERVIX is 10 mm in area of deepest invasion.
6. Lymphatic invasion by tumor IS identified but is FOCAL.
7. The NUCLEAR GRADE of the tumor is:
3 (Poorly-differentiated)
8. The tumor DOES NOT invade through the entire thickness of the cervix to involve contiguous parametrial tissues.
9. The tumor DOES NOT involve the uterine corpus.
10. The tumor DOES NOT involve the vagina at the margin.
11. Metastasis to regional lymph nodes is PRESENT.
12. The total number of metastatically-involved nodes is 2.
13. The total number of regional nodes examined is 10.
14. Extracapsular extension of metastatic tumor through the lymph node capsule is PRESENT.
15. DETAILED STAGING INFORMATION:
- A. TUMOR GROWTH: THE PRIMARY NEOPLASM IS CLASSIFIED AS:

TNM SCHEME	FIGO SCHEME	DEFINITION
T1b	IB	Tumor confined to uterus but larger than T1a2/ IA2
- B. REGIONAL LYMPH NODES are classified as:
N1 (Regional nodes ARE involved by metastasis)
- C. DISTANT METASTASES: The status of distant tissues is:
X (Status cannot be assessed)
15. THE FINAL STAGE OF THE TUMOR IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

{End of Report}

Source: NCI Genomic Data Commons file 359f7ad1-9fde-43b3-9715-9b01cca8dc55 (TCGA-C5-A0TN.33FE7DA3-EDB0-4301-BA6A-C51B75312FCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).